Somatic mutation profile of tumor specimen TCGA-B0-4700-01A (aliquot TCGA-B0-4700-01A-02D-1534-10) from TCGA case TCGA-B0-4700, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 60.3 years (22,034 days).
Specimen TCGA-B0-4700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38043721-87a4-4023-9d26-0594425a27a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4700-11A (Solid Tissue Normal), aliquot TCGA-B0-4700-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b379bf2-8e11-473d-8609-8c585489d2ee

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.3269+1G>A p.X1090_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as rs1064797371, COSV59903546; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.341-1G>T p.X114_splice | Splice Site (SNP) | VAF 18/222 reads (8%) | hotspot (GDC flag); catalogued as CS014769, CS107609, CS984220, COSV56543442, COSV56544761, COSV56548789; called by muse, mutect2
- AKAP4 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV62073944, COSV62074900; called by muse, mutect2
- BICD1 | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.986); catalogued as rs1555170325, COSV55676351; called by muse, mutect2, varscan2
- CFAP161 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs750046925, COSV54428664, COSV54428904; called by muse, mutect2
- CFAP47 | c.1191A>T p.K397N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.465); catalogued as COSV52881936; called by muse, mutect2
- FAM153A | c.307-1G>T p.X103_splice | Splice Site (SNP) | VAF 45/524 reads (9%) | catalogued as COSV62361247; called by muse, mutect2
- FMR1 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV54422560; called by muse, mutect2, varscan2
- GPR148 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV59307807; called by muse, mutect2, varscan2
- IGHV3-20 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.698); catalogued as rs1555454723; called by muse, mutect2
- LONRF3 | c.1327C>A p.P443T (on ENST00000371628 / NM_001031855.3; = p.P402T on NM_024778.5) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV59150803; called by muse, mutect2
- MIB1 | c.2044G>C p.V682L | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV55088699; called by muse, mutect2
- OR13C8 | c.802G>T p.V268F | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58610733; called by muse, mutect2, varscan2
- OR51L1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 52/526 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58624193, COSV58624780; called by muse, mutect2, varscan2
- OR52E8 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV66205383; called by muse, mutect2, varscan2
- OSTN | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs778562671, COSV59139146; called by muse, mutect2
- PAQR6 | c.51+1G>A p.X17_splice | Splice Site (SNP) | VAF 6/154 reads (4%) | catalogued as COSV52744536; called by muse, mutect2
- RBM44 | c.1199C>G p.S400C (on ENST00000611254; = p.S1034C on NM_001080504.2) | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57627885, COSV57628732; called by muse, mutect2
- STAG1 | c.3346C>T p.Q1116* | Nonsense Mutation (SNP) | VAF 26/310 reads (8%) | catalogued as COSV52604425; called by muse, mutect2
- TPM3 | c.582G>A p.M194I (on ENST00000368530 / NM_001364682.1; = p.M157I on NM_153649.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99666539; called by muse, mutect2
- TRPC4AP | c.1536G>C p.R512S | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV52677940, COSV99328727; called by muse, mutect2
- ZNF136 | c.186T>G p.N62K | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.968); catalogued as COSV59710383; called by muse, mutect2
- HMCN1 | c.6458del p.S2153Lfs*7 | Frame Shift Del (DEL) | VAF 49/386 reads (13%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.4343del p.L1448* | Frame Shift Del (DEL) | VAF 29/286 reads (10%) | called by mutect2, pindel, varscan2
- OR8B3 | c.756dup p.G253Wfs*9 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, varscan2
- SLC10A1 | c.526_528del p.L176del | In Frame Del (DEL) | VAF 59/562 reads (10%) | called by mutect2, pindel, varscan2
- SLK | c.2755_2765del p.Q919Efs*10 | Frame Shift Del (DEL) | VAF 19/190 reads (10%) | called by mutect2, pindel
- ZMYM6 | c.3260A>G p.H1087R | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- MOCS3 | c.714C>T p.N238= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV54865908; called by muse, mutect2, varscan2
- OR2F2 | c.855G>A p.L285= | Silent (SNP) | VAF 26/273 reads (10%) | catalogued as rs1462225046, COSV68832622; called by muse, mutect2
- SULT1A2 | c.120C>T p.D40= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs747536156, COSV57681123; called by muse, mutect2, varscan2
- TAAR5 | c.822C>A p.V274= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV57798657; called by muse, mutect2, varscan2
- TPGS2 | c.729G>C p.V243= | Silent (SNP) | VAF 28/670 reads (4%) | catalogued as COSV57539908; called by muse, mutect2
- TTN | c.44769C>T p.G14923= (on ENST00000591111; = p.G7499= on NM_003319.4) | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV59939930; called by muse, mutect2
